Somatic mutation profile of tumor specimen ALCH-B1VW-TTP1-A (aliquot ALCH-B1VW-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1VW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.0 years (24,847 days).
Specimen ALCH-B1VW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b475e5ec-a5b2-4928-9835-ad30c8c1a71b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VW-NB1-A (Blood Derived Normal), aliquot ALCH-B1VW-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cbb44b1-4ec2-47d1-bd7b-6279d4cb9269

The open-access MAF lists 1,322 somatic variants for this specimen: 931 protein-altering or splice-affecting, 247 silent, 144 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 792, Silent 247, Nonsense Mutation 78, Intron 61, RNA 34, Splice Site 19, Splice Region 17, Frame Shift Del 15, 3'UTR 15, 5'Flank 14, 5'UTR 13, 3'Flank 7.

Variants (750 of 1,322; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 104/776 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 42/292 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- ABCC8 | c.823-5G>A | Splice Region (SNP) | VAF 70/588 reads (12%) | catalogued as rs369489582; called by muse, mutect2, varscan2
- ABI3BP | c.1117A>G p.K373E | Missense Mutation (SNP) | VAF 55/422 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as rs1486875788; called by muse, mutect2, varscan2
- ADAM2 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs1025674397; called by muse, mutect2
- ADAMTS12 | c.1226G>T p.C409F | Missense Mutation (SNP) | VAF 67/343 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61256356; called by muse, mutect2, varscan2
- ADAMTS5 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 56/421 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.047); catalogued as COSV99537845; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 70/434 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750969735, COSV52813058; called by mutect2, varscan2
- ADCY2 | c.1590G>T p.M530I | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57875044; called by muse, mutect2, varscan2
- ADGRF2 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 62/478 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV57286430; called by muse, varscan2
- ADGRL2 | c.2618G>T p.R873L (on ENST00000370717 / NM_001366005.1; = p.R860L on NM_012302.4) | Missense Mutation (SNP) | VAF 130/1046 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM161445, COSV54651236; called by muse, mutect2, varscan2
- ADGRL3 | c.4273G>T p.E1425* (on ENST00000506720 / NM_001322402.2; = p.E1314* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 83/746 reads (11%) | catalogued as COSV72230153; called by muse, mutect2, varscan2
- ADRA2C | c.1225C>G p.R409G | Missense Mutation (SNP) | VAF 65/521 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV57467719; called by muse, mutect2, varscan2
- AGAP2 | c.1409G>T p.G470V (on ENST00000547588 / NM_001122772.2; = p.G134V on NM_014770.4) | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); catalogued as rs1053872729; called by muse, mutect2, varscan2
- AHCTF1 | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 52/455 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.631); catalogued as rs1017944410; called by muse, mutect2, varscan2
- AHNAK | c.7546C>A p.P2516T | Missense Mutation (SNP) | VAF 97/833 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99950017; called by muse, mutect2, varscan2
- AJAP1 | c.674C>G p.T225R | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV65454410; called by muse, varscan2
- AL031681.2 | c.3114G>C p.K1038N | Missense Mutation (SNP) | VAF 29/402 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as COSV100916932; called by muse, mutect2
- ANKRD11 | c.2661G>C p.E887D | Missense Mutation (SNP) | VAF 87/651 reads (13%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as rs771226129; called by muse, varscan2
- ANKRD35 | c.1558G>T p.G520* | Nonsense Mutation (SNP) | VAF 104/459 reads (23%) | catalogued as COSV62910013; called by muse, mutect2, varscan2
- APOB | c.11657G>T p.R3886L | Missense Mutation (SNP) | VAF 73/596 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.509); catalogued as rs1173547996; called by muse, mutect2, varscan2
- ARFGEF3 | c.1326G>T p.Q442H | Missense Mutation (SNP) | VAF 88/635 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52464539; called by muse, mutect2, varscan2
- ARHGAP4 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 80/577 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV63134446; called by muse, mutect2, varscan2
- ARHGEF3 | c.117G>T p.W39C | Missense Mutation (SNP) | VAF 56/516 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.965); catalogued as COSV58190720; called by muse, mutect2, varscan2
- ASIC4 | c.1135C>A p.L379M (on ENST00000347842 / NM_182847.3; = p.L398M on NM_018674.6) | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61732667; called by muse, varscan2
- ASPG | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as COSV71933608; called by muse, mutect2, varscan2
- ATG9B | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 22/175 reads (13%) | catalogued as COSV99872145; called by muse, mutect2, varscan2
- ATR | c.2647G>T p.D883Y | Missense Mutation (SNP) | VAF 53/570 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV63393037; called by muse, mutect2
- BCHE | c.959C>A p.P320Q | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013070; called by muse, mutect2, varscan2
- BIN2 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 37/584 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV57204345; called by muse, mutect2
- BRINP3 | c.471C>A p.S157R | Missense Mutation (SNP) | VAF 96/715 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV66523789, COSV66528036; called by muse, mutect2, varscan2
- BTK | c.1620C>A p.F540L | Missense Mutation (SNP) | VAF 80/940 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV58119513; called by muse, mutect2
- C6orf118 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 66/781 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.193); catalogued as rs149970829; called by muse, mutect2
- CACNA1A | c.4265G>T p.G1422V | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64212289; called by muse, varscan2
- CACNA1D | c.6101G>A p.R2034Q (on ENST00000350061 / NM_001128840.3; = p.R2054Q on NM_000720.4) | Missense Mutation (SNP) | VAF 65/405 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.503); catalogued as rs771758707, COSV55464316; called by muse, mutect2, varscan2
- CADM3 | c.409G>T p.G137C (on ENST00000368125 / NM_001127173.3; = p.G171C on NM_021189.5) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63686843; called by muse, mutect2
- CADM3 | c.410G>T p.G137V (on ENST00000368125 / NM_001127173.3; = p.G171V on NM_021189.5) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV63687032; called by muse, mutect2
- CALCR | c.1046C>A p.A349E (on ENST00000649521 / NM_001164737.2; = p.A333E on NM_001742.4) | Missense Mutation (SNP) | VAF 72/912 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV64010399; called by muse, mutect2
- CAMSAP3 | c.3001C>T p.R1001W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs775944769; called by mutect2, varscan2
- CAPN14 | c.867G>T p.W289C | Missense Mutation (SNP) | VAF 65/422 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs952284688; called by muse, mutect2, varscan2
- CASS4 | c.2287G>T p.A763S | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371811746; called by muse, mutect2, varscan2
- CBLB | c.974G>T p.R325M | Missense Mutation (SNP) | VAF 125/1069 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99913830; called by muse, mutect2, varscan2
- CCDC180 | c.4828G>T p.D1610Y | Missense Mutation (SNP) | VAF 61/500 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63828829; called by muse, mutect2, varscan2
- CD36 | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 146/1404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59213256; called by muse, mutect2, varscan2
- CDH7 | c.2033G>T p.R678L | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.695); catalogued as COSV59882171; called by muse, mutect2, varscan2
- CDHR2 | c.2563G>T p.G855W | Missense Mutation (SNP) | VAF 50/828 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56140280, COSV99991810; called by muse, mutect2
- CDK5R1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.984); catalogued as COSV55578507; called by muse, mutect2, varscan2
- CELSR2 | c.4768G>A p.V1590M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs750030005, COSV99602899; called by muse, mutect2, varscan2
- CEP170 | c.2008G>T p.G670* | Nonsense Mutation (SNP) | VAF 90/805 reads (11%) | catalogued as COSV60510833; called by muse, mutect2, varscan2
- CEP350 | c.5519G>A p.S1840N | Missense Mutation (SNP) | VAF 91/750 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1425228037; called by muse, mutect2, varscan2
- CFAP54 | c.5080C>A p.Q1694K | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1224361405; called by muse, mutect2
- CHD8 | c.1801G>T p.E601* (on ENST00000646647 / NM_001170629.2; = p.E322* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 75/739 reads (10%) | catalogued as rs1555316520; called by muse, mutect2, varscan2
- CMTR2 | c.199A>T p.K67* | Nonsense Mutation (SNP) | VAF 28/207 reads (14%) | catalogued as COSV57603172; called by muse, mutect2, varscan2
- CNPPD1 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 58/516 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99811360; called by muse, mutect2, varscan2
- COL17A1 | c.2557C>T p.L853F | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.224); catalogued as COSV104422120; called by muse, mutect2
- COL1A2 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 104/1433 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51953119; called by muse, mutect2
- COL6A2 | c.2237C>A p.A746E | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV56008499; called by muse, mutect2, varscan2
- COL6A5 | c.3904G>T p.G1302C | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV55217547; called by muse, mutect2, varscan2
- COL6A6 | c.6781C>T p.Q2261* | Nonsense Mutation (SNP) | VAF 18/151 reads (12%) | catalogued as rs1185991808; called by muse, mutect2, varscan2
- COL9A2 | c.584C>A p.A195E | Missense Mutation (SNP) | VAF 141/854 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs764157850, COSV65608064; called by muse, mutect2, varscan2
- CPT1A | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 73/487 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV55758731; called by muse, mutect2, varscan2
- CPVL | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 66/469 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV99605140; called by muse, mutect2, varscan2
- CRACD | c.962G>T p.R321M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV51714869; called by muse, mutect2, varscan2
- CRYBG1 | c.2900C>T p.T967I | Missense Mutation (SNP) | VAF 16/446 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV100954373; called by muse, mutect2
- CSMD3 | c.8770C>T p.P2924S (on ENST00000297405 / NM_001363185.1; = p.P2755S on NM_052900.3) | Missense Mutation (SNP) | VAF 66/603 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.61); catalogued as COSV52155351, COSV52167751; called by muse, mutect2, varscan2
- CTDP1 | c.1633G>T p.G545C | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99310629; called by muse, mutect2, varscan2
- CYP11B2 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 101/690 reads (15%) | catalogued as COSV59994484; called by muse, mutect2, varscan2
- DCAF12L2 | c.1160C>A p.A387D | Missense Mutation (SNP) | VAF 61/412 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.08); catalogued as COSV100758677; called by muse, mutect2, varscan2
- DCHS1 | c.1905C>A p.S635R | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201154636; called by muse, mutect2, varscan2
- DEFA4 | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV52404667; called by muse, mutect2, varscan2
- DISC1 | c.69C>A p.G23= | Splice Region (SNP) | VAF 153/1113 reads (14%) | catalogued as rs768658770; called by muse, mutect2, varscan2
- DLG5 | c.3172G>T p.G1058W | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs200325993; called by muse, mutect2, varscan2
- DMAC2 | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55728061; called by muse, mutect2, varscan2
- DMD | c.4222C>A p.Q1408K | Missense Mutation (SNP) | VAF 132/882 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV63751167; called by muse, mutect2, varscan2
- DMKN | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.071); catalogued as rs1416259763; called by muse, mutect2, varscan2
- DOK6 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 42/526 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66927337; called by muse, mutect2
- DPF3 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 58/448 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV63502732; called by muse, mutect2, varscan2
- DPP6 | c.946G>T p.A316S (on ENST00000377770 / NM_001364500.2; = p.A254S on NM_001936.5) | Missense Mutation (SNP) | VAF 44/377 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV100123888, COSV59635442; called by muse, mutect2, varscan2
- EPHA6 | c.2387-1G>C p.X796_splice (on ENST00000389672 / NM_001080448.3; = p.X188_splice on NM_173655.4) | Splice Site (SNP) | VAF 52/451 reads (12%) | catalogued as COSV67559133; called by muse, mutect2, varscan2
- EPS8L3 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs745436307; called by muse, mutect2, varscan2
- ERAP1 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 34/674 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as COSV57089896; called by muse, mutect2
- ERC1 | c.3059G>A p.R1020K (on ENST00000360905 / NM_178040.4; = p.R992K on NM_178039.4) | Missense Mutation (SNP) | VAF 35/319 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.138); catalogued as COSV61697326, COSV61698607; called by muse, mutect2, varscan2
- FAM83H | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 78/538 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101187017; called by muse, mutect2, varscan2
- FAT3 | c.3929C>T p.T1310I | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53134031; called by muse, mutect2, varscan2
- FERD3L | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 97/699 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51763167, COSV99284669; called by muse, mutect2, varscan2
- FGD4 | c.2051G>T p.R684I | Missense Mutation (SNP) | VAF 51/433 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV56783999; called by muse, mutect2, varscan2
- FIBIN | c.156C>A p.C52* | Nonsense Mutation (SNP) | VAF 58/484 reads (12%) | catalogued as COSV59413632; called by muse, mutect2, varscan2
- FIGNL2 | c.900C>A p.D300E | Missense Mutation (SNP) | VAF 39/373 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.516); catalogued as rs1344895087; called by muse, mutect2
- FNDC1 | c.1926C>A p.N642K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as rs1033460923, COSV51934873; called by muse, mutect2, varscan2
- FOXD3 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs771563410; called by muse, mutect2, varscan2
- FOXO1 | c.1627G>T p.V543L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.155); catalogued as rs1288963657; called by muse, mutect2
- FRMD7 | c.495C>T p.H165= | Splice Region (SNP) | VAF 69/771 reads (9%) | catalogued as rs766400857; called by muse, mutect2
- FUT11 | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as rs1357555316; called by muse, mutect2, varscan2
- GATAD1 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 54/552 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs1017952508; called by muse, mutect2
- GIMAP4 | c.197C>G p.T66S | Missense Mutation (SNP) | VAF 197/944 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99072238; called by muse, mutect2, varscan2
- GIMAP8 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 73/347 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100217309; called by muse, mutect2, varscan2
- GJD4 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1179441178; called by muse, mutect2, varscan2
- GLA | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 96/922 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM051069, CM066861; called by muse, mutect2, varscan2
- GLI2 | c.4039G>A p.A1347T (on ENST00000361492 / NM_001374353.1; = p.A1364T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100082652, COSV58044277; called by muse, mutect2, varscan2
- GLYATL2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.105); catalogued as COSV54850813; called by muse, mutect2
- GPD1L | c.774C>G p.C258W | Missense Mutation (SNP) | VAF 86/642 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56989306; called by muse, mutect2, varscan2
- GPR63 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 69/613 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013512; called by muse, mutect2, varscan2
- GRM4 | c.374C>A p.A125E | Missense Mutation (SNP) | VAF 46/395 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100946393; called by muse, mutect2, varscan2
- GRM7 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 60/529 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.118); catalogued as rs372059810; called by muse, mutect2, varscan2
- GUCY1A2 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.096); catalogued as rs1214622475; called by muse, mutect2
- H3-5 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 59/537 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs370904771, COSV61186642; called by muse, mutect2, varscan2
- HMCN1 | c.8202G>T p.E2734D | Missense Mutation (SNP) | VAF 106/778 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs1311868737; called by muse, mutect2, varscan2
- HMCN2 | c.10594del p.Q3532Sfs*13 | Frame Shift Del (DEL) | VAF 53/314 reads (17%) | catalogued as rs1285388324; called by mutect2, varscan2
- HTRA3 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV56473296; called by muse, mutect2, varscan2
- ID4 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV66343197; called by muse, mutect2, varscan2
- IGF2BP1 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 52/485 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771495169, COSV51732125; called by muse, mutect2, varscan2
- IL12RB2 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 79/729 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV52020541; called by muse, mutect2, varscan2
- IL17RA | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1226991818; called by muse, mutect2, varscan2
- IL18R1 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 47/581 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV52125850, COSV99294921; called by muse, mutect2
- IL36RN | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 130/648 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs768514559; called by muse, mutect2, varscan2
- IQSEC3 | c.2196C>A p.D732E (on ENST00000538872 / NM_001170738.2; = p.D429E on NM_015232.1) | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100407124; called by muse, mutect2, varscan2
- IRF2 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 55/705 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV101165738; called by muse, mutect2
- ITGAE | c.2191G>A p.V731M | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV53995063; called by muse, mutect2, varscan2
- ITPR2 | c.4040A>G p.N1347S | Missense Mutation (SNP) | VAF 60/696 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs1330707682; called by muse, mutect2
- KCNA1 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 86/1064 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.282); catalogued as rs962399769; ClinVar: uncertain significance; called by muse, mutect2
- KCNA10 | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 66/526 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV100871466; called by muse, mutect2, varscan2
- KCNG1 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 133/749 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65370431; called by muse, mutect2, varscan2
- KIAA1549L | c.4226G>A p.R1409H (on ENST00000321505; = p.R1706H on NM_012194.3) | Missense Mutation (SNP) | VAF 78/776 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565978185, COSV58585296; called by muse, mutect2
- KIAA1755 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.398); catalogued as COSV54078248, COSV54081187; called by muse, mutect2, varscan2
- KIF21B | c.1771G>T p.E591* | Nonsense Mutation (SNP) | VAF 22/162 reads (14%) | catalogued as COSV59759922; called by muse, mutect2
- KIF25 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 130/337 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV99053271; called by muse, mutect2, varscan2
- KNG1 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53976591; called by muse, mutect2, varscan2
- KRT31 | c.1037G>C p.R346P | Missense Mutation (SNP) | VAF 91/765 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV99289414; called by muse, mutect2, varscan2
- KRT82 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs770881217; called by muse, mutect2, varscan2
- L1TD1 | c.1503del p.A502Pfs*23 | Frame Shift Del (DEL) | VAF 97/698 reads (14%) | catalogued as rs752779955; called by mutect2, pindel, varscan2
- LAMA2 | c.4406G>T p.C1469F | Missense Mutation (SNP) | VAF 50/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70343876; called by muse, mutect2, varscan2
- LATS2 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.074); catalogued as rs370973977; called by muse, mutect2, varscan2
- LIPJ | c.662A>T p.D221V | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as rs768853203; called by muse, mutect2, varscan2
- LRATD1 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 58/349 reads (17%) | catalogued as COSV99039156; called by muse, mutect2, varscan2
- LRP1B | c.2133G>T p.W711C | Missense Mutation (SNP) | VAF 93/887 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67278639; called by muse, mutect2, varscan2
- MACC1 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100256341; called by muse, mutect2, varscan2
- MAGEB6B | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 89/517 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs371855458; called by muse, mutect2, varscan2
- MALT1 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 65/651 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs757096789, COSV61934102; called by muse, mutect2, varscan2
- MAP3K1 | c.3250G>T p.D1084Y | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV68123441; called by muse, mutect2
- MARCHF2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1425564961, COSV53104572; called by muse, mutect2
- MASP2 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 62/463 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV68896147; called by muse, mutect2, varscan2
- MAT1A | c.405+1G>A p.X135_splice | Splice Site (SNP) | VAF 30/977 reads (3%) | catalogued as COSV64745103; called by muse, mutect2
- MED22 | c.12G>C p.Q4H | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs138400651; called by muse, mutect2, varscan2
- MEIS1 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 62/436 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99715353; called by muse, mutect2, varscan2
- MIA2 | c.1204G>T p.V402L | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99698107; called by muse, mutect2
- MIA3 | c.4327C>T p.R1443W | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs749287544; called by muse, mutect2, varscan2
- MMP3 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 90/730 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as rs377547395; called by muse, mutect2, varscan2
- MNDA | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 77/509 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs559502950, COSV63740322; called by muse, mutect2, varscan2
- MTHFD1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 122/1139 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs1254034887; called by muse, mutect2, varscan2
- MYBPC2 | c.678C>A p.Y226* | Nonsense Mutation (SNP) | VAF 40/472 reads (8%) | catalogued as rs80199747, COSV63093994; called by muse, mutect2
- MYDGF | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 48/574 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV53561514; called by muse, mutect2
- MYH4 | c.4511G>C p.R1504P | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55117797; called by muse, mutect2, varscan2
- MYH8 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 141/868 reads (16%) | catalogued as COSV67964748; called by muse, mutect2, varscan2
- MYLK3 | c.1059G>T p.R353S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101189078, COSV101189104; called by muse, mutect2, varscan2
- NLRP3 | c.1095T>G p.H365Q | Missense Mutation (SNP) | VAF 93/651 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs1424785713; called by muse, mutect2, varscan2
- NLRP3 | c.2870G>A p.W957* | Nonsense Mutation (SNP) | VAF 132/929 reads (14%) | catalogued as COSV100276392; called by muse, mutect2, varscan2
- NPAS4 | c.2159C>A p.P720Q | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV60649590; called by muse, mutect2, varscan2
- NRN1 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55205371; called by muse, mutect2, varscan2
- NSUN7 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57272517; called by muse, mutect2
- NTNG1 | c.795G>T p.R265S | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs375156633; called by muse, mutect2
- OCA2 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 113/783 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs769767739; called by muse, mutect2, varscan2
- OPN3 | c.697C>G p.R233G | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV59363910; called by muse, mutect2, varscan2
- OR11H6 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs765329894; called by muse, mutect2, varscan2
- OR14K1 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 74/555 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV99314997; called by muse, mutect2, varscan2
- OR2L3 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 95/938 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100741913, COSV63454624; called by muse, varscan2
- OR2L5 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 98/633 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.124); catalogued as rs1413144223; called by muse, mutect2, varscan2
- OR2W3 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 63/332 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs201811838, COSV64456738; called by muse, mutect2, varscan2
- OR4A16 | c.899G>T p.W300L | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as COSV100125175; called by muse, mutect2, varscan2
- OR4A5 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.248); catalogued as rs760971695, COSV100157251; called by muse, mutect2, varscan2
- OR4F6 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 173/590 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs550275593; called by muse, mutect2, varscan2
- OR4S2 | c.782C>A p.T261K | Missense Mutation (SNP) | VAF 48/459 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV56746202; called by muse, mutect2, varscan2
- OR52I1 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 75/579 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757607134; called by muse, mutect2, varscan2
- OR5AC2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV100684304; called by muse, mutect2, varscan2
- OR8J1 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV57318243; called by muse, mutect2, varscan2
- OTOF | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV99718751; called by muse, mutect2, varscan2
- PAMR1 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 52/501 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV53517630; called by muse, mutect2, varscan2
- PCDHA2 | c.2198C>G p.A733G | Missense Mutation (SNP) | VAF 148/757 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV65364430; called by muse, mutect2, varscan2
- PCSK5 | c.3916G>C p.G1306R | Missense Mutation (SNP) | VAF 66/651 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as COSV101377705; called by muse, mutect2
- PDZD2 | c.5875G>A p.E1959K | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as rs757774681, COSV56872049; called by muse, mutect2, varscan2
- PDZRN3 | c.2812G>T p.V938L | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs780293470, COSV55209234, COSV99071462; called by muse, mutect2, varscan2
- PEG3 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 45/428 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs372007366; called by muse, mutect2, varscan2
- PHOX2B | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); catalogued as COSV56930570; called by muse, mutect2, varscan2
- PIDD1 | c.1381G>T p.V461L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs769008134; called by mutect2, varscan2
- PIK3R1 | c.1930G>T p.G644C (on ENST00000521381 / NM_181523.3; = p.G374C on NM_181504.4) | Missense Mutation (SNP) | VAF 104/406 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57130919, COSV57140018; called by muse, mutect2, varscan2
- PLOD2 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 84/767 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1325370070; called by muse, mutect2, varscan2
- PML | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as COSV51444563; called by muse, mutect2, varscan2
- PNMA3 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64721737; called by muse, mutect2, varscan2
- POF1B | c.1655G>T p.R552M | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV99426818, COSV99427308; called by muse, mutect2
- POM121L12 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.347); catalogued as rs748643466, COSV68692714; called by muse, mutect2, varscan2
- POTEC | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 100/1210 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62802880; called by muse, mutect2
- POU3F4 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 55/411 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV100937274; called by muse, mutect2, varscan2
- PPHLN1 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); catalogued as rs1426278015; called by muse, mutect2
- PPP1R36 | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs138901715; called by muse, mutect2, varscan2
- PPP6R1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.561); catalogued as rs775261948; called by muse, mutect2, varscan2
- PRKDC | c.4084G>T p.D1362Y | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs369191886; called by muse, mutect2, varscan2
- PRPS1 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 92/1026 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV65054148; called by muse, mutect2
- PRSS55 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 62/510 reads (12%) | catalogued as COSV60809458; called by muse, mutect2, varscan2
- PRSS55 | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 46/682 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV60808910; called by muse, mutect2
- PSG7 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 116/1100 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs368995857; called by muse, mutect2, varscan2
- PTEN | c.758del p.I253Tfs*3 | Frame Shift Del (DEL) | VAF 67/727 reads (9%) | catalogued as COSV64299826, COSV64310715; called by mutect2, pindel
- PTGS2 | c.1592G>T p.W531L | Missense Mutation (SNP) | VAF 80/485 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66572013; called by muse, mutect2, varscan2
- PTPRT | c.2768C>A p.S923Y | Missense Mutation (SNP) | VAF 72/531 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV62017760; called by muse, mutect2, varscan2
- RALGDS | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 114/860 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100924559; called by mutect2, varscan2
- RASAL3 | c.524T>C p.M175T | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs749451728; called by muse, mutect2, varscan2
- RASSF2 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV65082559; called by muse, mutect2
- RBM10 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 52/365 reads (14%) | catalogued as COSV100237272; called by muse, mutect2, varscan2
- RBMX | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 39/491 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); catalogued as rs746321201; called by muse, mutect2
- RCAN2 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV57815360, COSV57818467; called by muse, mutect2, varscan2
- RNASEH1 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs761632461; called by muse, mutect2
- ROBO2 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 61/552 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs781379035; called by muse, mutect2, varscan2
- ROPN1B | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 39/429 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs200722264; called by muse, mutect2
- ROPN1B | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV52541968, COSV99305452; called by muse, mutect2, varscan2
- RORC | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 117/577 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775194753, COSV59094271; called by muse, mutect2, varscan2
- RP1L1 | c.5854G>T p.G1952W | Missense Mutation (SNP) | VAF 43/453 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV101223233; called by muse, mutect2
- RPA4 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61295989; called by muse, mutect2
- RPTOR | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 91/747 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60807997; called by muse, mutect2, varscan2
- RRAS2 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 54/570 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160017680; called by muse, mutect2
- RRH | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 89/709 reads (13%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs1405819546; called by muse, mutect2, varscan2
- RYR1 | c.7106G>A p.R2369Q | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as rs777966555, COSV62109276; called by muse, mutect2, varscan2
- SAMSN1 | c.524C>A p.T175K | Missense Mutation (SNP) | VAF 82/660 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53478979; called by muse, mutect2, varscan2
- SCARA5 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 87/699 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100108004; called by muse, mutect2, varscan2
- SCGN | c.165G>C p.M55I | Missense Mutation (SNP) | VAF 59/473 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV58544906; called by muse, mutect2, varscan2
- SDCCAG8 | c.1479A>G p.I493M | Missense Mutation (SNP) | VAF 77/560 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1423681895; called by muse, mutect2, varscan2
- SDK2 | c.1007C>A p.P336Q | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101169042; called by muse, mutect2, varscan2
- SEMG2 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 23/558 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.175); catalogued as COSV65647612; called by muse, mutect2
- SERPINI2 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 45/552 reads (8%) | catalogued as COSV52984285; called by muse, mutect2
- SH3TC1 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs757887780, COSV99794889; called by muse, mutect2, varscan2
- SIGLEC10 | c.1111C>A p.L371M | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100218536, COSV100218674; called by muse, mutect2
- SIGLEC12 | c.1248del p.S417Afs*2 (on ENST00000291707 / NM_053003.4; = p.S299Afs*2 on NM_033329.2) | Frame Shift Del (DEL) | VAF 50/386 reads (13%) | catalogued as rs1289779974, COSV52463137; called by mutect2, pindel, varscan2
- SLC26A3 | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 70/963 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.737); catalogued as COSV60640379; called by muse, mutect2
- SLC6A8 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53472021; called by muse, mutect2
- SLITRK1 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 142/1242 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.951); catalogued as COSV65674582, COSV65675692; called by muse, mutect2, varscan2
- SLITRK4 | c.1055C>G p.P352R | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.565); catalogued as COSV100567190; called by muse, mutect2, varscan2
- SOAT1 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV62656515; called by muse, mutect2, varscan2
- SPAG17 | c.2398G>T p.A800S | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768906298; called by muse, mutect2, varscan2
- SPATA48 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 55/544 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51670241; called by muse, mutect2, varscan2
- SPATC1 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV66298022; called by muse, mutect2, varscan2
- SPEF2 | c.5302C>A p.P1768T | Missense Mutation (SNP) | VAF 76/516 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs769479360; called by muse, mutect2, varscan2
- SPTAN1 | c.2350C>G p.L784V | Missense Mutation (SNP) | VAF 27/460 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV63989994; called by muse, mutect2
- SPTBN5 | c.6092G>T p.R2031L | Missense Mutation (SNP) | VAF 99/553 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58018716; called by muse, mutect2, varscan2
- SRMS | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 22/174 reads (13%) | catalogued as rs1454242642; called by muse, mutect2, varscan2
- SSR4 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 51/541 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782038768; called by muse, mutect2
- STK39 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 143/630 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs779099780; called by muse, mutect2, varscan2
- SVOPL | c.1041G>T p.M347I (on ENST00000419765; = p.M195I on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/684 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV55993897; called by muse, mutect2, varscan2
- TBC1D21 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as rs766533178, COSV55995765; called by muse, mutect2, varscan2
- TDRD10 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV52726404; called by muse, mutect2, varscan2
- THBS2 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 114/439 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs751145010; called by muse, mutect2, varscan2
- THSD7B | c.2681G>T p.R894L | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV55736702; called by muse, mutect2
- TLR4 | c.92A>T p.E31V | Missense Mutation (SNP) | VAF 130/1008 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1163840909; called by muse, varscan2
- TMCO4 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 107/645 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.67); catalogued as rs775455299; called by muse, mutect2, varscan2
- TMEM120A | c.388A>G p.K130E | Missense Mutation (SNP) | VAF 59/653 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1554560798; called by muse, mutect2
- TMEM19 | c.545G>C p.C182S | Missense Mutation (SNP) | VAF 70/511 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1263577662; called by muse, mutect2, varscan2
- TNN | c.2309G>T p.G770V | Missense Mutation (SNP) | VAF 151/973 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53429511; called by muse, mutect2, varscan2
- TPO | c.2069C>A p.S690Y | Missense Mutation (SNP) | VAF 132/750 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61100694; called by muse, mutect2, varscan2
- TPX2 | c.101G>T p.W34L | Missense Mutation (SNP) | VAF 76/386 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55923600; called by muse, mutect2, varscan2
- TRBV3-1 | c.20G>T p.C7F | Missense Mutation (SNP) | VAF 54/558 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1007590067; called by muse, mutect2
- TRIM3 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV61985960; called by muse, mutect2, varscan2
- TRIM51 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 52/460 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as rs367940835, COSV55267170; called by muse, mutect2, varscan2
- TRIML2 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 70/498 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58716533; called by muse, mutect2, varscan2
- TRPV5 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 109/392 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as rs1316263780; called by muse, mutect2, varscan2
- TTC21B | c.1185+1G>T p.X395_splice | Splice Site (SNP) | VAF 164/795 reads (21%) | catalogued as rs1375925318; called by muse, mutect2, varscan2
- TUBA3D | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 119/503 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58310581; called by muse, mutect2, varscan2
- TYK2 | c.2822G>T p.R941L | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs554711523, COSV99314389; called by muse, mutect2, varscan2
- TYRO3 | c.2446G>A p.G816R | Missense Mutation (SNP) | VAF 78/832 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99778101; called by muse, mutect2
- ULK2 | c.1760A>G p.D587G | Missense Mutation (SNP) | VAF 56/415 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV64449136; called by muse, mutect2, varscan2
- UMODL1 | c.3502C>T p.P1168S (on ENST00000408910 / NM_001004416.2; = p.P1296S on NM_173568.3) | Missense Mutation (SNP) | VAF 63/425 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs1315004171, COSV68569398; called by muse, mutect2, varscan2
- UNC5B | c.1520C>A p.P507Q | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); catalogued as COSV100101545; called by muse, mutect2
- VCAN | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 36/806 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54118672; called by muse, mutect2
- VNN3 | c.614G>C p.G205A | Missense Mutation (SNP) | VAF 70/548 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51590833; called by muse, mutect2, varscan2
- VWA5B1 | c.1460G>A p.C487Y | Missense Mutation (SNP) | VAF 81/720 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1005786450; called by muse, mutect2, varscan2
- WDFY4 | c.117C>A p.S39R | Missense Mutation (SNP) | VAF 85/606 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1168037676; called by muse, mutect2, varscan2
- WHRN | c.2234G>C p.R745P | Missense Mutation (SNP) | VAF 97/719 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as CM1411371, COSV54333761; called by muse, mutect2, varscan2
- XKR7 | c.1538C>A p.A513D | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as rs780725931; called by muse, mutect2, varscan2
- XPC | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV53203497, COSV53205050; called by muse, mutect2, varscan2
- XRN2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 84/673 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426725850, COSV65868255; called by muse, mutect2, varscan2
- ZDHHC17 | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 36/388 reads (9%) | catalogued as COSV100602148; called by muse, mutect2
- ZFPM2 | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 106/872 reads (12%) | catalogued as COSV65872331; called by muse, mutect2, varscan2
- ZIC3 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV54972646; called by muse, varscan2
- ZIC5 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.374); catalogued as rs745913274, COSV99940731; called by muse, mutect2, varscan2
- ZIK1 | c.117C>A p.D39E | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56737438; called by muse, mutect2
- ZNF135 | c.1186C>A p.P396T (on ENST00000313434 / NM_001289401.2; = p.P408T on NM_003436.4) | Missense Mutation (SNP) | VAF 67/856 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.244); catalogued as rs772827796; called by muse, mutect2
- ZNF365 | c.1175G>T p.R392M | Missense Mutation (SNP) | VAF 10/259 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); catalogued as COSV67925266; called by muse, mutect2
- ZNF440 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 68/659 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV100407736; called by muse, mutect2, varscan2
- ZNF518B | c.1943A>T p.E648V | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs74524439; called by muse, mutect2, varscan2
- ZNF670 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 59/359 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100829258; called by muse, mutect2, varscan2
- ZNF699 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 80/524 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV58026422; called by muse, mutect2, varscan2
- ZNF716 | c.355G>T p.G119* | Nonsense Mutation (SNP) | VAF 64/448 reads (14%) | catalogued as rs782809581; called by muse, mutect2, varscan2
- ABCA12 | c.2849A>T p.N950I (on ENST00000272895 / NM_173076.3; = p.N632I on NM_015657.3) | Missense Mutation (SNP) | VAF 100/827 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ABCA13 | c.13906C>A p.L4636M | Missense Mutation (SNP) | VAF 79/701 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA8 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.395); called by muse, mutect2
- ABCA8 | c.852G>T p.L284F | Missense Mutation (SNP) | VAF 27/397 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- ABCC9 | c.1981C>A p.R661S | Missense Mutation (SNP) | VAF 114/856 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCG8 | c.1560C>A p.N520K | Missense Mutation (SNP) | VAF 135/837 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ABL1 | c.1424-2A>T p.X475_splice | Splice Site (SNP) | VAF 56/497 reads (11%) | called by muse, mutect2, varscan2
- AC004593.2 | c.683A>C p.Y228S | Missense Mutation (SNP) | VAF 148/1307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC100868.1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 68/524 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACR | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACTR3B | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADAMDEC1 | c.467G>T p.R156I | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- ADAMTS20 | c.1627G>T p.G543W | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADD2 | c.650C>A p.A217E | Missense Mutation (SNP) | VAF 52/405 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ADGRB3 | c.2257+1G>T p.X753_splice | Splice Site (SNP) | VAF 39/223 reads (17%) | called by muse, mutect2, varscan2
- ADGRB3 | c.3344C>A p.S1115Y | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ADGRV1 | c.7585G>T p.D2529Y | Missense Mutation (SNP) | VAF 293/1294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRA2B | c.1123G>C p.V375L | Missense Mutation (SNP) | VAF 92/664 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- AGO1 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 25/609 reads (4%) | called by muse, mutect2
- AKAP12 | c.4985C>T p.P1662L | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKAP4 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 127/754 reads (17%) | called by muse, mutect2, varscan2
- AKAP4 | c.27+1G>T p.X9_splice | Splice Site (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- AKAP4 | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2
- AKAP6 | c.2565A>T p.A855= | Splice Region (SNP) | VAF 38/290 reads (13%) | called by muse, mutect2, varscan2
- AL121899.2 | c.2089A>G p.N697D | Missense Mutation (SNP) | VAF 83/805 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALG13 | c.2405C>A p.P802Q | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2
- ALPK2 | c.4450C>A p.P1484T | Missense Mutation (SNP) | VAF 48/364 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AMIGO2 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 71/596 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMMECR1 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 62/610 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- ANKFN1 | c.2164C>T p.L722F | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKFN1 | c.2948C>T p.P983L (on ENST00000653862; = p.P836L on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/1074 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6793_6794dup p.N2265Kfs*156 | Frame Shift Ins (INS) | VAF 78/363 reads (21%) | called by mutect2, pindel, varscan2
- ANKIB1 | c.1107A>T p.Q369H | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ANKRD11 | c.2604G>C p.M868I | Missense Mutation (SNP) | VAF 90/624 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- ANKRD17 | c.5626G>T p.G1876C | Missense Mutation (SNP) | VAF 163/1462 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ANKRD18A | c.2191G>T p.D731Y | Missense Mutation (SNP) | VAF 22/337 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ANKRD30B | c.1742G>T p.C581F | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- ANKRD9 | c.853G>T p.V285L | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANXA6 | c.318G>C p.S106= | Splice Region (SNP) | VAF 98/398 reads (25%) | called by muse, mutect2, varscan2
- AP2B1 | c.331G>T p.G111W | Missense Mutation (SNP) | VAF 94/674 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APBB2 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- APOB | c.2516C>G p.P839R | Missense Mutation (SNP) | VAF 75/517 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOBEC3A | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 22/637 reads (3%) | called by muse, mutect2
- ARHGAP22 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 19/525 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP25 | c.278C>T p.P93L (on ENST00000409202 / NM_001007231.3; = p.P86L on NM_014882.3) | Missense Mutation (SNP) | VAF 68/419 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- ARHGAP36 | c.936G>T p.M312I | Missense Mutation (SNP) | VAF 51/319 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARHGAP44 | c.649A>T p.T217S | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ARID3C | c.389G>T p.R130M | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ARX | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ASB12 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ASB18 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- ATG3 | c.395A>T p.D132V | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP13A3 | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 86/604 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ATP13A3 | c.1957G>T p.G653* | Nonsense Mutation (SNP) | VAF 87/611 reads (14%) | called by muse, mutect2, varscan2
- ATP1A4 | c.1077G>T p.M359I | Missense Mutation (SNP) | VAF 56/548 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ATP2B2 | c.1813C>A p.P605T (on ENST00000352432; = p.P571T on NM_001683.5) | Missense Mutation (SNP) | VAF 96/679 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ATR | c.2458G>T p.V820F | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATRX | c.4831G>A p.V1611I | Missense Mutation (SNP) | VAF 54/687 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); called by muse, mutect2
- AWAT1 | c.697A>T p.K233* | Nonsense Mutation (SNP) | VAF 115/1064 reads (11%) | called by muse, mutect2, varscan2
- BAAT | c.715C>A p.Q239K | Missense Mutation (SNP) | VAF 47/421 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- BCORL1 | c.4225T>A p.C1409S | Missense Mutation (SNP) | VAF 103/928 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BEND3 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 61/427 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BEST2 | c.178C>A p.R60S | Missense Mutation (SNP) | VAF 45/434 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- BLM | c.892A>T p.T298S | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BMPER | c.1270G>T p.V424L | Missense Mutation (SNP) | VAF 66/478 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BPIFA3 | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 82/459 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- BPIFB2 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- BRF2 | c.693C>A p.F231L | Missense Mutation (SNP) | VAF 43/576 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- BRINP3 | c.472A>G p.K158E | Missense Mutation (SNP) | VAF 97/714 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- BRWD3 | c.4456G>A p.V1486I | Missense Mutation (SNP) | VAF 80/789 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- BST1 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 63/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTK | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 54/511 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C11orf42 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 68/566 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C1QC | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- C1QTNF1 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 91/763 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- C6orf118 | c.1205del p.K402Sfs*32 | Frame Shift Del (DEL) | VAF 164/502 reads (33%) | called by mutect2, pindel, varscan2
- C8orf37 | c.277G>T p.V93F | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.234); called by muse, mutect2
- CABP1 | c.1000C>G p.L334V (on ENST00000316803 / NM_001033677.1; = p.L131V on NM_004276.5) | Missense Mutation (SNP) | VAF 52/538 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- CACNA1C | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 136/831 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CACNA1H | c.5950G>C p.A1984P | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- CADPS | c.1748A>C p.Q583P | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CAMSAP2 | c.1906G>C p.E636Q (on ENST00000236925 / NM_001297707.2; = p.E625Q on NM_203459.3) | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CAPNS2 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 42/329 reads (13%) | called by muse, mutect2, varscan2
- CAPZA3 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 89/573 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CASP8 | c.1-3A>T | Splice Region (SNP) | VAF 30/387 reads (8%) | called by muse, mutect2
- CBX8 | c.864G>T p.R288S | Missense Mutation (SNP) | VAF 54/538 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- CCDC136 | c.1255C>A p.L419M | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CCDC144A | c.3941A>T p.Q1314L | Missense Mutation (SNP) | VAF 39/607 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- CCDC50 | c.937T>G p.F313V | Missense Mutation (SNP) | VAF 50/507 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.036); called by muse, mutect2
- CCDC63 | c.458A>C p.Q153P | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- CCKBR | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CCT6A | c.1222G>T p.V408F | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CCT8L2 | c.217G>C p.A73P | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CD163 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 68/499 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD244 | c.611C>A p.P204H (on ENST00000368033 / NM_001166663.2; = p.P199H on NM_016382.4) | Missense Mutation (SNP) | VAF 146/571 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CD300C | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 61/429 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CDCA2 | c.2206G>T p.G736C | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH4 | c.885C>A p.Y295* | Nonsense Mutation (SNP) | VAF 69/247 reads (28%) | called by muse, mutect2
- CDK13 | c.3814G>T p.E1272* | Nonsense Mutation (SNP) | VAF 25/201 reads (12%) | called by muse, mutect2, varscan2
- CDO1 | c.501del p.F167Lfs*13 | Frame Shift Del (DEL) | VAF 125/578 reads (22%) | called by mutect2, pindel, varscan2
- CELF3 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 107/457 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CELF4 | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- CELSR1 | c.5709dup p.G1904Wfs*43 | Frame Shift Ins (INS) | VAF 62/494 reads (13%) | called by mutect2, pindel, varscan2
- CENPE | c.8013G>C p.E2671D | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CEP83 | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2
- CFAP251 | c.592del p.R198Efs*52 | Frame Shift Del (DEL) | VAF 76/622 reads (12%) | called by mutect2, pindel, varscan2
- CFAP99 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 79/618 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- CHD5 | c.3317G>A p.G1106D | Missense Mutation (SNP) | VAF 57/462 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD5 | c.1242C>A p.D414E | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CHML | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 74/844 reads (9%) | called by muse, mutect2
- CHRNB3 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST2 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHST6 | c.980T>A p.L327H | Missense Mutation (SNP) | VAF 144/856 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CILP2 | c.2600G>A p.R867K | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CKAP5 | c.4783A>T p.I1595F | Missense Mutation (SNP) | VAF 38/511 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2
- CLDN10 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- CLIP2 | c.325G>C p.A109P | Missense Mutation (SNP) | VAF 175/631 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTN5 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 29/191 reads (15%) | called by muse, mutect2, varscan2
- COL11A2 | c.3332G>T p.G1111V (on ENST00000341947 / NM_080680.3; = p.G1004V on NM_080679.2) | Missense Mutation (SNP) | VAF 89/560 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL15A1 | c.1189G>T p.G397W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- COL1A1 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 96/543 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- COL27A1 | c.3530G>A p.G1177E | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- COL4A2 | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 34/357 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- COL4A5 | c.2042-1G>C p.X681_splice | Splice Site (SNP) | VAF 66/744 reads (9%) | called by muse, mutect2
- COL6A2 | c.1671+1G>T p.X557_splice | Splice Site (SNP) | VAF 96/702 reads (14%) | called by muse, mutect2, varscan2
- COL6A2 | c.1931G>T p.R644M | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL9A3 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 69/437 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COLGALT2 | c.1137-1G>T p.X379_splice | Splice Site (SNP) | VAF 52/416 reads (13%) | called by muse, mutect2, varscan2
- COX10 | c.1079A>T p.H360L | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CRB1 | c.2982del p.E995Sfs*27 | Frame Shift Del (DEL) | VAF 31/304 reads (10%) | called by mutect2, pindel, varscan2
- CROCC2 | c.4840C>A p.Q1614K | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CRYBA2 | c.591C>A p.H197Q | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- CSMD2 | c.1110C>A p.N370K | Missense Mutation (SNP) | VAF 94/754 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.255); called by muse, mutect2
- CSNK1G1 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 75/457 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSRNP1 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 62/491 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CTNND2 | c.1685A>T p.Q562L | Missense Mutation (SNP) | VAF 220/1000 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CTU1 | c.695A>T p.Y232F | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- CUL3 | c.2176-1G>T p.X726_splice | Splice Site (SNP) | VAF 41/205 reads (20%) | called by muse, mutect2, varscan2
- CUX2 | c.2272C>A p.P758T | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.119); called by muse, varscan2
- CYFIP2 | c.2881G>A p.V961M (on ENST00000616178 / NM_001291722.2; = p.V936M on NM_014376.4) | Missense Mutation (SNP) | VAF 125/444 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CYP7A1 | c.756C>A p.S252R | Missense Mutation (SNP) | VAF 77/719 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DAGLA | c.2504G>T p.S835I | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- DBNL | c.727G>T p.V243L (on ENST00000448521 / NM_001014436.3; = p.V244L on NM_014063.7) | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- DBX1 | c.684G>A p.W228* | Nonsense Mutation (SNP) | VAF 101/848 reads (12%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.289G>T p.V97F | Missense Mutation (SNP) | VAF 50/524 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2
- DCAF8L1 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 72/565 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- DCDC1 | c.4046G>T p.G1349V (on ENST00000597505 / NM_001367979.1; = p.G456V on NM_020869.3) | Missense Mutation (SNP) | VAF 43/486 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- DDIT4L | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 93/651 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DDX60 | c.3667G>T p.D1223Y | Missense Mutation (SNP) | VAF 98/977 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- DGAT2L6 | c.494C>A p.S165* | Nonsense Mutation (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2, varscan2
- DHX57 | c.1335G>T p.R445S | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- DISC1 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.853); called by muse, mutect2
- DMD | c.1810G>C p.A604P | Missense Mutation (SNP) | VAF 38/417 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- DNAAF2 | c.1448G>T p.R483I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- DNAAF6 | c.181A>G p.M61V | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2
- DNAH14 | c.6079T>A p.C2027S (on ENST00000445597; = p.C2680S on NM_001367479.1) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- DNAH3 | c.3403G>A p.V1135M | Missense Mutation (SNP) | VAF 79/480 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DNAH5 | c.6652G>A p.G2218S | Missense Mutation (SNP) | VAF 86/1243 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.013); called by muse, mutect2
- DNTT | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 72/412 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- DOCK10 | c.4514T>A p.L1505H | Missense Mutation (SNP) | VAF 36/361 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DOCK3 | c.349C>A p.H117N | Missense Mutation (SNP) | VAF 67/528 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DOHH | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DOK3 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- DPP6 | c.1279G>T p.E427* (on ENST00000377770 / NM_001364500.2; = p.E365* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 42/597 reads (7%) | called by muse, mutect2
- DPY19L1 | c.258G>T p.M86I | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DPY19L2 | c.1471A>T p.R491* | Nonsense Mutation (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
- DRP2 | c.1464C>A p.S488R | Missense Mutation (SNP) | VAF 70/622 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- DSPP | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 82/687 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- DTHD1 | c.280G>T p.E94* (on ENST00000456874; = p.E219* on NM_001170700.3) | Nonsense Mutation (SNP) | VAF 44/451 reads (10%) | called by muse, mutect2
- EEF2K | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- EFCAB3 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFCAB8 | c.2647G>T p.D883Y | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- EFHB | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 92/670 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- EHMT1 | c.3840G>T p.E1280D | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- EIF4G3 | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 41/390 reads (11%) | called by muse, mutect2, varscan2
- ELOVL6 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 93/657 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ENOX1 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ENPP3 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 56/688 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EPHA4 | c.1672G>T p.V558L | Missense Mutation (SNP) | VAF 60/626 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2
- EPM2A | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 91/759 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ESPNL | c.1446G>T p.Q482H | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); called by muse, mutect2
- EVC | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 86/458 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- EXT1 | c.1489G>T p.V497L | Missense Mutation (SNP) | VAF 96/727 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXTL3 | c.1879G>T p.A627S | Missense Mutation (SNP) | VAF 54/500 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- EYS | c.3518G>T p.G1173V | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- FABP7 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 81/603 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM155B | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.051); called by muse, mutect2
- FAM170A | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- FAM83B | c.1519G>C p.A507P | Missense Mutation (SNP) | VAF 63/604 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- FAM83B | c.1744G>T p.D582Y | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- FAM83B | c.2297G>T p.S766I | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- FASN | c.5114G>T p.R1705L | Missense Mutation (SNP) | VAF 81/573 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- FAT3 | c.12217G>A p.G4073R | Missense Mutation (SNP) | VAF 83/708 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBLN5 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 156/1215 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- FHAD1 | c.434A>C p.Q145P | Missense Mutation (SNP) | VAF 102/782 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FHOD3 | c.588C>A p.Y196* | Nonsense Mutation (SNP) | VAF 29/490 reads (6%) | called by muse, mutect2
- FKBP11 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 36/641 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLNA | c.3881A>T p.K1294M | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- FLNC | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 104/377 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMNL3 | c.1088A>T p.E363V | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FMO2 | c.789G>T p.W263C | Missense Mutation (SNP) | VAF 81/635 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- FNDC1 | c.5655G>T p.E1885D | Missense Mutation (SNP) | VAF 80/659 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FOXN3 | c.1063A>T p.I355F (on ENST00000261302; = p.I333F on NM_005197.4) | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.114); called by muse, varscan2
- FOXN4 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- FZD10 | c.244C>A p.H82N | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GABRQ | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 24/243 reads (10%) | called by muse, mutect2, varscan2
- GABRQ | c.1645C>G p.Q549E | Missense Mutation (SNP) | VAF 72/734 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.079); called by muse, mutect2
- GADL1 | c.1008G>T p.M336I | Missense Mutation (SNP) | VAF 102/1086 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.1); called by muse, mutect2
- GALNT14 | n.386C>A | Splice Region (SNP) | VAF 57/517 reads (11%) | called by muse, mutect2, varscan2
- GAP43 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 41/283 reads (14%) | called by muse, mutect2, varscan2
- GAP43 | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GDAP2 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- GDI1 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- GFRA1 | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 30/985 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- GGA3 | c.1361C>G p.S454* (on ENST00000537686 / NM_138619.4; = p.S421* on NM_014001.5) | Nonsense Mutation (SNP) | VAF 92/662 reads (14%) | called by muse, mutect2, varscan2
- GLB1L3 | c.1334A>T p.N445I | Missense Mutation (SNP) | VAF 46/514 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GLI1 | c.2803C>A p.Q935K | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GMCL2 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 35/682 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- GMEB1 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 38/403 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GNRHR | c.163T>A p.S55T | Missense Mutation (SNP) | VAF 121/936 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPA33 | c.849G>T p.E283D | Missense Mutation (SNP) | VAF 134/648 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, varscan2
- GPR137B | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- GPR174 | c.501A>T p.K167N | Missense Mutation (SNP) | VAF 76/636 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- GPRC5B | c.1181C>G p.P394R | Missense Mutation (SNP) | VAF 60/463 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- GRB7 | c.322A>C p.S108R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, varscan2
- GRIA2 | c.2129G>T p.G710V | Missense Mutation (SNP) | VAF 90/902 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIK2 | c.1749-2A>T p.X583_splice | Splice Site (SNP) | VAF 26/184 reads (14%) | called by muse, mutect2, varscan2
- GRM2 | c.2570C>A p.T857N | Missense Mutation (SNP) | VAF 85/747 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- GSG1L | c.865C>A p.H289N (on ENST00000447459 / NM_001109763.2; = p.H134N on NM_144675.2) | Missense Mutation (SNP) | VAF 83/640 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GYPA | c.317C>A p.T106K | Missense Mutation (SNP) | VAF 66/914 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.893); called by muse, mutect2
- GYPC | c.190+1G>T p.X64_splice | Splice Site (SNP) | VAF 148/743 reads (20%) | called by muse, mutect2, varscan2
- GZMA | c.411A>C p.K137N | Missense Mutation (SNP) | VAF 19/541 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2
- HELLS | c.1979G>T p.S660I | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- HELZ | c.5090G>T p.G1697V | Missense Mutation (SNP) | VAF 84/899 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- HEPH | c.1315G>T p.E439* (on ENST00000343002; = p.E172* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/272 reads (10%) | called by muse, mutect2
- HEPH | c.2502C>G p.Y834* (on ENST00000343002; = p.Y567* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/612 reads (7%) | called by muse, mutect2
- HOXA7 | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 30/255 reads (12%) | called by muse, mutect2, varscan2
- HOXC5 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 93/517 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA12A | c.666A>T p.A222= | Splice Region (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- HTR3C | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 53/605 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- HTR3D | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGBP1 | c.995A>G p.Y332C | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- IGFBP4 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHD | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 170/1192 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- IGHG3 | c.524C>G p.P175R | Missense Mutation (SNP) | VAF 77/511 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHMBP2 | c.1235+1G>T p.X412_splice | Splice Site (SNP) | VAF 11/180 reads (6%) | called by muse, mutect2
- IGHV2-26 | c.205del p.A70Hfs*15 | Frame Shift Del (DEL) | VAF 88/795 reads (11%) | called by mutect2, pindel, varscan2
- IGKV1-16 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 62/488 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV6-21 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 122/1066 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV6D-21 | c.322C>A p.H108N | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- IGSF1 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 29/440 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); called by muse, mutect2
- IGSF11 | c.734G>T p.G245V (on ENST00000393775 / NM_001015887.3; = p.G244V on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL10RA | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL17B | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 105/507 reads (21%) | called by muse, mutect2, varscan2
- IL1F10 | c.453C>A p.S151R | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IL27 | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INHA | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- IRS1 | c.1886G>T p.S629I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, varscan2
- IRX4 | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ISL1 | c.223T>A p.Y75N | Missense Mutation (SNP) | VAF 78/834 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2
- ITK | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 197/869 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ITK | c.398G>T p.C133F | Missense Mutation (SNP) | VAF 43/1081 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITPR2 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 88/631 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- IVNS1ABP | c.1013del p.S338Tfs*9 | Frame Shift Del (DEL) | VAF 108/812 reads (13%) | called by mutect2, pindel*, varscan2
- JHY | c.1473G>T p.M491I | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.035); called by muse, mutect2
- KCNA10 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 89/699 reads (13%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- KCNH1 | c.1398T>A p.F466L (on ENST00000271751 / NM_172362.3; = p.F439L on NM_002238.4) | Missense Mutation (SNP) | VAF 58/339 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ4 | c.827A>T p.K276M | Missense Mutation (SNP) | VAF 68/417 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- KCNN1 | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- KCNU1 | c.2530C>A p.P844T | Missense Mutation (SNP) | VAF 21/309 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- KIAA1109 | c.14422A>T p.T4808S | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- KIAA1328 | c.1083G>T p.Q361H | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIAA1549L | c.1267A>G p.T423A (on ENST00000321505; = p.T720A on NM_012194.3) | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIAA2026 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- KIF13A | c.5336A>C p.H1779P | Missense Mutation (SNP) | VAF 70/564 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- KL | c.2650G>C p.D884H | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHDC8A | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KLHL31 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT25 | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 79/613 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT39 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 93/609 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- KRT6A | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 74/878 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- KRTAP16-1 | c.971G>T p.C324F | Missense Mutation (SNP) | VAF 58/413 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- KRTAP22-1 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 114/975 reads (12%) | PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KRTAP4-11 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 108/960 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, varscan2
- KY | c.1807G>A p.G603S | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- LAMA4 | c.4726G>T p.E1576* (on ENST00000230538 / NM_001105206.3; = p.E1569* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 113/1004 reads (11%) | called by muse, mutect2, varscan2
- LAMA5 | c.5562A>T p.K1854N | Missense Mutation (SNP) | VAF 80/403 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- LAMA5 | c.2530A>T p.R844W | Missense Mutation (SNP) | VAF 100/455 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- LAMB1 | c.1887C>G p.I629M | Missense Mutation (SNP) | VAF 98/457 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LGALS9C | c.131+7G>A | Splice Region (SNP) | VAF 138/541 reads (26%) | called by muse, varscan2
- LMBR1 | c.363T>A p.F121L | Missense Mutation (SNP) | VAF 92/787 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- LOXHD1 | c.4456G>T p.G1486* | Nonsense Mutation (SNP) | VAF 25/285 reads (9%) | called by muse, mutect2
- LPGAT1 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 26/225 reads (12%) | called by muse, mutect2, varscan2
- LRP1 | c.5237G>T p.G1746V | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRP1B | c.7996G>T p.G2666* | Nonsense Mutation (SNP) | VAF 89/495 reads (18%) | called by muse, mutect2, varscan2
- LRRC15 | c.1590G>T p.W530C | Missense Mutation (SNP) | VAF 60/444 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC55 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 63/576 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC6 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 51/394 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- LRRN2 | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRTM4 | c.938G>T p.W313L | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRTM2 | c.31A>T p.R11W | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- LRTM2 | c.914G>T p.R305M | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTA4H | c.1417A>T p.S473C | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.055); called by muse, mutect2
- LTBP1 | c.2792G>A p.C931Y (on ENST00000404816 / NM_206943.4; = p.C605Y on NM_000627.4) | Missense Mutation (SNP) | VAF 88/809 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LUM | c.156C>A p.Y52* | Nonsense Mutation (SNP) | VAF 90/689 reads (13%) | called by muse, mutect2, varscan2
- LYST | c.8665G>T p.D2889Y | Missense Mutation (SNP) | VAF 75/698 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MAGEC1 | c.3230C>G p.S1077* | Nonsense Mutation (SNP) | VAF 21/234 reads (9%) | called by muse, mutect2
- MAGED2 | c.846G>T p.R282S | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MALRD1 | c.3626G>T p.G1209V | Missense Mutation (SNP) | VAF 62/449 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MANBA | c.2677A>T p.T893S (on ENST00000642252; = p.T847S on NM_005908.4) | Missense Mutation (SNP) | VAF 94/1007 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.687); called by muse, mutect2
- MBD1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 29/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- MBNL3 | c.969G>T p.M323I | Missense Mutation (SNP) | VAF 32/363 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2
- MCF2L2 | c.2862G>T p.M954I | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2
- MED12 | c.5777C>A p.S1926Y | Missense Mutation (SNP) | VAF 74/792 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.399); called by muse, mutect2
- MED12L | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MED12L | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MEIS1 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 93/558 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- MEOX2 | c.555C>A p.S185R | Missense Mutation (SNP) | VAF 72/490 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MERTK | c.2543C>A p.S848* | Nonsense Mutation (SNP) | VAF 52/631 reads (8%) | called by muse, mutect2
- MGAM | c.3453G>T p.W1151C | Missense Mutation (SNP) | VAF 156/561 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MICAL3 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 75/395 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MID1 | c.920A>T p.E307V | Missense Mutation (SNP) | VAF 81/649 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- MLYCD | c.1279G>T p.G427W | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMACHC | c.756dup p.T253Yfs*57 | Frame Shift Ins (INS) | VAF 15/143 reads (10%) | called by pindel, varscan2
- MMP8 | c.315C>A p.N105K | Missense Mutation (SNP) | VAF 64/518 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MRAS | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 80/557 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRC1 | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 166/1146 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- MROH9 | c.1636C>T p.L546F | Missense Mutation (SNP) | VAF 43/366 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MSTO1 | c.291-7C>G | Splice Region (SNP) | VAF 86/798 reads (11%) | called by muse, mutect2, varscan2
- MTMR8 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 86/821 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2
- MUC12 | c.1489C>A p.H497N (on ENST00000379442; = p.H354N on NM_001164462.1) | Missense Mutation (SNP) | VAF 135/539 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- MUC16 | c.43258C>A p.Q14420K | Missense Mutation (SNP) | VAF 64/544 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- MUC4 | c.8125G>T p.D2709Y | Missense Mutation (SNP) | VAF 69/743 reads (9%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2
- MUC5B | c.3890G>A p.R1297K | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- MUC6 | c.3107_3117del p.L1036Rfs*54 | Frame Shift Del (DEL) | VAF 68/598 reads (11%) | called by mutect2, pindel
- MXRA5 | c.4700C>A p.A1567E | Missense Mutation (SNP) | VAF 59/417 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH11 | c.5021C>A p.T1674K | Missense Mutation (SNP) | VAF 223/1473 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MYH2 | c.4702C>A p.Q1568K | Missense Mutation (SNP) | VAF 103/727 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- MYLK3 | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 69/509 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO10 | c.3725G>C p.R1242P | Missense Mutation (SNP) | VAF 69/930 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO16 | c.5497A>T p.K1833* | Nonsense Mutation (SNP) | VAF 84/874 reads (10%) | called by muse, mutect2
- MYO7A | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- MYO7B | c.5093C>A p.T1698K | Missense Mutation (SNP) | VAF 60/626 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.079); called by muse, mutect2
- MYOD1 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 43/376 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYT1L | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 124/890 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NAA10 | c.90C>A p.Y30* | Nonsense Mutation (SNP) | VAF 112/1009 reads (11%) | called by muse, mutect2, varscan2
- NAALADL2 | c.1899C>A p.L633= | Splice Region (SNP) | VAF 79/681 reads (12%) | called by muse, mutect2, varscan2
- NAV3 | c.5258G>C p.C1753S | Missense Mutation (SNP) | VAF 44/343 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCDN | c.546C>A p.C182* | Nonsense Mutation (SNP) | VAF 72/597 reads (12%) | called by muse, mutect2, varscan2
- NCKAP1L | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 59/572 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NDST4 | c.1245G>T p.M415I | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.1); called by muse, mutect2
- NECTIN1 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 117/830 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- NES | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 118/404 reads (29%) | called by muse, mutect2, varscan2
- NEXMIF | c.2105T>A p.V702D | Missense Mutation (SNP) | VAF 58/634 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.054); called by muse, mutect2
- NFATC1 | c.2781C>A p.D927E (on ENST00000427363 / NM_001278669.2; = p.D914E on NM_172387.3) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NKAIN3 | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 41/431 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NKX6-1 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 74/721 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NLRC3 | c.1021C>A p.H341N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- NLRC5 | c.2602G>T p.E868* | Nonsense Mutation (SNP) | VAF 73/579 reads (13%) | called by muse, mutect2, varscan2
- NLRP2 | c.2707G>T p.V903L | Missense Mutation (SNP) | VAF 64/668 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NLRP4 | c.692A>T p.D231V | Missense Mutation (SNP) | VAF 56/482 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP5 | c.3208C>A p.L1070M | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- NMNAT2 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 114/780 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPL | c.303dup p.E102Rfs*5 | Frame Shift Ins (INS) | VAF 111/936 reads (12%) | called by mutect2, pindel, varscan2
- NPVF | c.143G>C p.R48T | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.081); called by muse, varscan2
- NRIP1 | c.2099G>T p.G700V | Missense Mutation (SNP) | VAF 62/633 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.626); called by muse, mutect2
- NRK | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 61/640 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NT5DC4 | c.24C>G p.N8K | Missense Mutation (SNP) | VAF 142/626 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NT5DC4 | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- NTRK3 | c.2426G>T p.R809M (on ENST00000360948 / NM_001012338.2; = p.R795M on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 216/674 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NTSR1 | c.579G>T p.W193C | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NUP214 | c.6212G>T p.G2071V | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- NUP98 | c.2708_2716del p.K903_K905del | In Frame Del (DEL) | VAF 74/766 reads (10%) | called by mutect2, pindel
- NXF5 | n.599A>T | Splice Region (SNP) | VAF 68/585 reads (12%) | called by muse, mutect2, varscan2
- NXPH2 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 109/948 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- OBSCN | c.22541C>A p.T7514N | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- OCRL | c.1583G>T p.S528I | Missense Mutation (SNP) | VAF 113/959 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ODF2 | c.1466G>T p.S489I (on ENST00000434106 / NM_153433.2; = p.S465I on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/760 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OGDHL | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR14C36 | c.469C>G p.H157D | Missense Mutation (SNP) | VAF 44/432 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- OR2T1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 48/368 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- OR2Z1 | c.70C>G p.R24G | Missense Mutation (SNP) | VAF 62/452 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR4D10 | c.497T>G p.L166R | Missense Mutation (SNP) | VAF 43/562 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR4D6 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR51I2 | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 51/548 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR5B3 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 79/811 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2
- OR5H15 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 29/258 reads (11%) | called by muse, varscan2
- OR5L1 | c.721T>A p.C241S | Missense Mutation (SNP) | VAF 52/436 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5M10 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 19/638 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- OR5M8 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 29/310 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2
- OR7G2 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 78/828 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- PAK1IP1 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 69/611 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PAK3 | c.626G>A p.R209K (on ENST00000262836 / NM_001324328.2; = p.R194K on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/1074 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); called by muse, mutect2
- PAN2 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 56/499 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PARD3B | c.1047A>T p.Q349H | Missense Mutation (SNP) | VAF 121/1252 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.804); called by muse, mutect2
- PASD1 | c.1899G>T p.Q633H | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2
- PATJ | c.3238G>T p.G1080W | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH10 | c.1498T>A p.Y500N | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB11 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 30/594 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2
- PCDHB13 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 81/979 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA1 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 126/556 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- PCDHGA10 | c.980A>G p.D327G | Missense Mutation (SNP) | VAF 36/504 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA6 | c.2384A>C p.Q795P | Missense Mutation (SNP) | VAF 53/929 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- PCDHGB2 | c.988C>A p.H330N | Missense Mutation (SNP) | VAF 38/769 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2
- PCDHGB5 | c.1200G>T p.L400F | Missense Mutation (SNP) | VAF 34/696 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDHGB6 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.139); called by muse, mutect2
- PCK1 | c.1186+8C>T | Splice Region (SNP) | VAF 103/645 reads (16%) | called by muse, mutect2, varscan2
- PDE10A | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- PDE3B | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- PDE3B | c.3250G>C p.A1084P | Missense Mutation (SNP) | VAF 99/833 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PDE4A | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); called by muse, varscan2
- PDE4D | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 24/445 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2
- PDE5A | c.1573-3T>A | Splice Region (SNP) | VAF 90/696 reads (13%) | called by muse, mutect2, varscan2
- PDZD3 | c.1058C>A p.P353H (on ENST00000531114; = p.P273H on NM_024791.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.153); called by muse, mutect2
- PEG3 | c.481+3G>T | Splice Region (SNP) | VAF 58/392 reads (15%) | called by muse, mutect2, varscan2
- PGBD2 | c.918G>T p.L306F | Missense Mutation (SNP) | VAF 76/850 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- PGBD2 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 76/855 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2
- PGLYRP2 | c.717C>G p.S239R | Missense Mutation (SNP) | VAF 61/410 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- PHF6 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 57/495 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PHF6 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 47/494 reads (10%) | called by muse, mutect2
- PIEZO2 | c.7314C>A p.D2438E | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PKHD1 | c.9548T>G p.V3183G | Missense Mutation (SNP) | VAF 142/1205 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PLCB4 | c.1823C>G p.A608G | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- PLCH2 | c.3059C>A p.A1020E | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PLEKHA7 | c.2056A>T p.I686F | Missense Mutation (SNP) | VAF 43/460 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2
- PLEKHH2 | c.2830+1G>T p.X944_splice | Splice Site (SNP) | VAF 21/151 reads (14%) | called by muse, mutect2, varscan2
- PLIN4 | c.2357G>T p.C786F (on ENST00000301286; = p.C801F on NM_001367868.2) | Missense Mutation (SNP) | VAF 64/654 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2
- PLPPR5 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 100/716 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PLXNA3 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PLXNA4 | c.1888C>T p.H630Y | Missense Mutation (SNP) | VAF 41/377 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PLXNB2 | c.4271T>A p.L1424H | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNMA5 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- POLG | c.1568A>T p.D523V | Missense Mutation (SNP) | VAF 105/818 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- POP7 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POTEJ | c.2198C>A p.P733H | Missense Mutation (SNP) | VAF 176/870 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- POU3F4 | c.445G>T p.G149* | Nonsense Mutation (SNP) | VAF 56/406 reads (14%) | called by mutect2, varscan2
- PPFIA2 | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- PPP2R2B | c.812C>A p.P271Q (on ENST00000394409; = p.P337Q on NM_181674.2) | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2
- PPP2R2B | c.706A>G p.N236D (on ENST00000394409; = p.N302D on NM_181674.2) | Missense Mutation (SNP) | VAF 39/370 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- PRKCG | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 45/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROM1 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRG1 | c.289G>C p.V97L | Missense Mutation (SNP) | VAF 103/850 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PSAT1 | c.524G>A p.C175Y | Missense Mutation (SNP) | VAF 139/1253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PSD2 | c.290G>T p.R97M | Missense Mutation (SNP) | VAF 44/869 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2
- PTCD1 | c.923G>C p.R308P | Missense Mutation (SNP) | VAF 74/756 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2
- PTPRO | c.2144T>G p.M715R | Missense Mutation (SNP) | VAF 162/1156 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PYGL | c.1655_1656insT p.E553Gfs*13 | Frame Shift Ins (INS) | VAF 107/881 reads (12%) | called by mutect2, pindel, varscan2
- PYURF | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 85/672 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB39B | c.412G>C p.A138P | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2
- RAB6B | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 81/683 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RAD51AP2 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 78/515 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- RASAL1 | c.1913T>A p.V638E | Missense Mutation (SNP) | VAF 45/427 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RASSF5 | c.939C>A p.D313E | Missense Mutation (SNP) | VAF 125/958 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RBBP5 | c.30del p.Q11Rfs*18 | Frame Shift Del (DEL) | VAF 32/223 reads (14%) | called by mutect2, pindel, varscan2
- RBM26 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 20/595 reads (3%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2
- RBM6 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 54/438 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, varscan2
- RBM6 | c.2602A>G p.S868G | Missense Mutation (SNP) | VAF 49/327 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBMXL1 | c.832G>T p.G278* | Nonsense Mutation (SNP) | VAF 122/1172 reads (10%) | called by muse, mutect2
- RCBTB1 | c.412C>A p.H138N | Missense Mutation (SNP) | VAF 57/398 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- REEP2 | c.418-6G>T | Splice Region (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- RFX5 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 96/950 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RFX6 | c.2570C>A p.T857K | Missense Mutation (SNP) | VAF 104/890 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RGS14 | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 48/1008 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
572 further variants in this file (181 protein-altering or splice-affecting, 247 silent, 144 other) are not listed here.
